Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5741, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5741-01A (Primary Tumor).

Diagnosis

1. Poorly differentiated, bilateral adenocarcinoma of the prostate across the organ. Maximum tumor diameter 5.5 cm. Gleason 4+5=9 (Gleason 5: 20%). Extensive extraprostatic tumor growth in the bilateral rectolateral and bilateral basal regions, as well as extensive bilateral infiltration of the seminal vesicles. Multifocal tumor involvement of perineural sheaths. Multifocal tumor infiltration of the surgical preparation margin in the left basal and right rectolateral region (max. contact line 3 mm in the left basal region); Gleason 4 and Gleason 5 portions immediately at the margin. Multifocal evidence of lymph vessel invasion. No unequivocal evidence of blood vessel invasion.

In addition, numerous foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia.

2. 2 tumor-free lymph nodes.

3. 1.5 cm carcinoma metastasis without evidence of extranodal tumor growth in one of three lymph nodes.

Summary tumor classification

pT3b, max. tumor diameter 5.5 cm, Gleason 4+5=9 (Gleason 5 = 20%), L1, V0, pN1 (1/5), R1.

Remark

In contrast to the prior punch biopsies, a Gleason 5 portion of 30% is now identifiable in the main preparation.

Additional immunohistochemical studies were initiated to clarify the vascular status. The results will be presented in a follow-up report.

Follow-up report**Microscopy**

(Immunohistochemistry: CD31, D2-40)

In the immunohistochemical studies on two representative tumor blocks, there is no evidence to suggest the presence of tumorous vessel invasion.

The final tumor classification is thus as follows:

pT3a. Gleason 4+5=9 (Gleason 4: 50%, Gleason 4: 30%), pN0 (0/3), L0, V0, R1.

Source: NCI Genomic Data Commons file 9f7622a3-abd3-4fc5-af77-92373a346d9f (TCGA-CH-5741.87C977CC-2A28-49C9-ADAF-F67C0BC208C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).